Somatic mutation profile of tumor specimen TCGA-ER-A193-06A (aliquot TCGA-ER-A193-06A-12D-A197-08) from TCGA case TCGA-ER-A193, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.2 years (22,702 days).
Specimen TCGA-ER-A193-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac66fb86-62d7-477b-83aa-b2bfd979dabd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A193-10A (Blood Derived Normal), aliquot TCGA-ER-A193-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4a06991-8ad1-431f-8d15-67d50b009a13

The open-access MAF lists 2,304 somatic variants for this specimen: 1,546 protein-altering or splice-affecting, 711 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,408, Silent 711, Nonsense Mutation 89, Intron 23, Splice Site 23, Splice Region 14, RNA 9, Frame Shift Del 8, 3'UTR 7, 5'Flank 4, Frame Shift Ins 2, 3'Flank 2.

Variants (750 of 2,304; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GCDH | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs754312389, COSV53366588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, mutect2, varscan2
- A2ML1 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV55288712; called by muse, mutect2, varscan2
- AACS | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753261331, COSV55536821; called by muse, varscan2
- AADAC | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs532572215, COSV51759323; called by muse, mutect2, varscan2
- AAK1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1053268820, COSV68643822; called by muse, mutect2
- ABCA10 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.308); catalogued as rs202012056; called by muse, mutect2, varscan2
- ABCA9 | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs189147388, COSV60624931; called by muse, mutect2, varscan2
- ABCB1 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV55951745, COSV55961061; called by muse, mutect2, varscan2
- ABCB11 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as rs200174512; ClinVar: benign; called by muse, mutect2
- ABCB5 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as COSV51709891; called by muse, mutect2, varscan2
- ABCC3 | c.4464G>A p.M1488I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs1567840192, COSV53325924; called by muse, mutect2, varscan2
- ABCC6 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52743962; called by muse, mutect2, varscan2
- ABCC9 | c.4225C>T p.P1409S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99686113; called by muse, mutect2, varscan2
- ABRA | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238355967, COSV61732447; called by muse, mutect2, varscan2
- AC008676.3 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs540171356, COSV56636734; called by muse, mutect2, varscan2
- AC008676.3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs912062768, COSV56636749; called by muse, mutect2, varscan2
- ACAD11 | c.2281C>T p.L761F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53896401; called by muse, mutect2, varscan2
- ACAN | c.7675C>T p.P2559S (on ENST00000560601 / NM_001369268.1; = p.P2422S on NM_001135.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.81); catalogued as rs1156317911; called by muse, mutect2
- ACSL5 | c.290G>A p.R97K (on ENST00000354273; = p.R153K on NM_016234.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV61130690; called by muse, mutect2, varscan2
- ACTL9 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV61005788; called by muse, mutect2, varscan2
- ACTRT1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV64419395; called by muse, mutect2, varscan2
- ACTRT2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV65759381; called by muse, mutect2, varscan2
- ACVR2B | c.656T>A p.F219Y | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61702276; called by muse, mutect2, varscan2
- ADAM18 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55847619; called by muse, mutect2, varscan2
- ADAM28 | c.1495C>T p.H499Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.13); catalogued as COSV56100621; called by muse, mutect2, varscan2
- ADAM28 | c.1825A>T p.N609Y | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV56100636; called by muse, mutect2, varscan2
- ADAM28 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV56100646; called by muse, mutect2, varscan2
- ADAM32 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV65948817; called by muse, mutect2, varscan2
- ADAMTS12 | c.4119G>A p.W1373* | Nonsense Mutation (SNP) | VAF 64/161 reads (40%) | catalogued as COSV61263279; called by muse, mutect2, varscan2
- ADAMTS17 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769415971, COSV51476461, COSV51486986; called by muse, mutect2, varscan2
- ADAMTS20 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV67131691; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADARB1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV62344365; called by muse, mutect2, varscan2
- ADCY4 | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60254375; called by muse, mutect2, varscan2
- ADCY5 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV59198048; called by muse, mutect2, varscan2
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ADGRF4 | c.1974G>A p.K658= | Splice Region (SNP) | VAF 24/72 reads (33%) | catalogued as COSV51952426; called by muse, mutect2
- ADGRF5 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51934005; called by muse, mutect2, varscan2
- ADGRL3 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV72268456, COSV72269289; called by muse, mutect2, varscan2
- ADGRL4 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV66061704, COSV66066683; called by muse, mutect2, varscan2
- ADGRV1 | c.2486T>C p.L829P | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67985371; called by muse, mutect2, varscan2
- ADGRV1 | c.5942T>C p.F1981S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985375; called by muse, mutect2, varscan2
- ADGRV1 | c.14827C>T p.P4943S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV101316134; called by muse, mutect2, varscan2
- ADGRV1 | c.14828C>T p.P4943L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV101316135; called by muse, mutect2, varscan2
- AGTR1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV62558268; called by muse, mutect2, varscan2
- AGTR2 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs868939201, COSV64156480; called by muse, mutect2, varscan2
- AKAP11 | c.2303A>C p.Q768P | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV50296998; called by muse, mutect2, varscan2
- AKAP3 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV50539353; called by muse, mutect2, varscan2
- AKAP3 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57416928; called by muse, mutect2, varscan2
- AKAP6 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773848125, COSV55214154; called by muse, mutect2, varscan2
- AKT1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV62573451; called by muse, mutect2, varscan2
- ALDH1B1 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs551352427, COSV66619728; called by muse, mutect2, varscan2
- ALG3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.896); catalogued as COSV56611574; called by muse, mutect2, varscan2
- ALKAL2 | c.396A>C p.K132N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344521046, COSV55243325; called by muse, mutect2, varscan2
- AMBRA1 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54052108; called by muse, mutect2, varscan2
- AMER2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs751976243, COSV63437578; called by muse, mutect2, varscan2
- AMPD3 | c.590-1G>A p.X197_splice (on ENST00000396553 / NM_001025389.2; = p.X206_splice on NM_000480.3) | Splice Site (SNP) | VAF 31/115 reads (27%) | catalogued as COSV67330985; called by muse, mutect2, varscan2
- ANGPTL1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV52366446; called by muse, mutect2, varscan2
- ANK3 | c.7537G>A p.E2513K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV55058315; called by muse, mutect2, varscan2
- ANKH | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.077); catalogued as COSV52480982; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV51847230; called by muse, mutect2, varscan2
- ANKRD12 | c.4934T>G p.L1645W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV50825360; called by muse, mutect2, varscan2
- ANKRD45 | c.209T>A p.L70H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60961100; called by mutect2, varscan2
- ANKS1A | c.2413C>A p.L805I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.997); catalogued as COSV64460771; called by muse, mutect2, varscan2
- ANKS1B | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs745539676, COSV61335090; called by muse, mutect2, varscan2
- ANO3 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56791506; called by muse, mutect2, varscan2
- ANXA6 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334144971; called by muse, mutect2
- APLP1 | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV55703454; called by muse, mutect2, varscan2
- APOB | c.13036A>G p.K4346E | Missense Mutation (SNP) | VAF 172/539 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51935645; called by muse, mutect2, varscan2
- APOB | c.4894G>A p.G1632S | Missense Mutation (SNP) | VAF 230/649 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.909); catalogued as COSV51935658; called by muse, mutect2, varscan2
- APOL1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV59869004; called by muse, mutect2, varscan2
- APPL1 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55700911, COSV55702810; called by muse, mutect2, varscan2
- APPL1 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55700917; called by muse, mutect2, varscan2
- ARAP1 | c.3235C>T p.R1079W (on ENST00000393609 / NM_001040118.2; = p.R834W on NM_015242.4) | Missense Mutation (SNP) | VAF 164/436 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146883151; called by muse, mutect2, varscan2
- ARAP2 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58286815; called by muse, mutect2, varscan2
- ARFGAP2 | c.1178T>A p.I393N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as COSV60301139; called by muse, mutect2, varscan2
- ARHGAP29 | c.3631A>G p.K1211E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); catalogued as COSV53111927; called by muse, mutect2, varscan2
- ARHGAP35 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.617); catalogued as COSV68331386; called by muse, mutect2, varscan2
- ARHGAP35 | c.1943T>C p.V648A | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.312); catalogued as COSV68331396; called by muse, mutect2, varscan2
- ARHGAP44 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99310969; called by muse, varscan2
- ARHGAP9 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as COSV62722576; called by muse, mutect2, varscan2
- ARHGEF28 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.311); catalogued as COSV55252771; called by muse, mutect2, varscan2
- ARHGEF28 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as rs760410003, COSV55256428; called by muse, mutect2, varscan2
- ARHGEF28 | c.2278C>A p.P760T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV55256448; called by muse, mutect2, varscan2
- ARHGEF40 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs777350548, COSV53880496; called by muse, mutect2, varscan2
- ARID2 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV57603871, COSV57603930; called by muse, mutect2, varscan2
- ARMC4 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as COSV59459566, COSV59463674; called by muse, mutect2, varscan2
- ARMC4 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs191594899, COSV53464637, COSV53465076; called by muse, mutect2, varscan2
- ARNTL2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.916); catalogued as COSV53825860; called by muse, mutect2, varscan2
- ARNTL2 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs756752847, COSV99667884; called by muse, mutect2, varscan2
- ARPP21 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51804797; called by muse, mutect2, varscan2
- ART3 | c.1090G>A p.G364S (on ENST00000355810 / NM_001377173.1; = p.G353S on NM_001179.6) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53575633; called by muse, mutect2, varscan2
- ART5 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV63364581; called by muse, mutect2, varscan2
- ASIC2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as COSV56762357; called by muse, mutect2, varscan2
- ASL | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.199); catalogued as COSV59188448; called by muse, mutect2, varscan2
- ASNS | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV51552366; called by muse, mutect2, varscan2
- ASTN1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763391667, COSV56064196; called by muse, mutect2, varscan2
- ASXL3 | c.5438G>A p.G1813E | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52466499; called by muse, mutect2, varscan2
- ATF1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV50394647; called by muse, mutect2, varscan2
- ATF4 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV57478985; called by muse, mutect2, varscan2
- ATG2A | c.2068G>T p.V690F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV65966884; called by muse, mutect2, varscan2
- ATG2B | c.2516C>T p.S839L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs1290466158, COSV63423145; called by muse, mutect2, varscan2
- ATG4C | c.1012+2T>C p.X338_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | catalogued as COSV58605636; called by muse, mutect2, varscan2
- ATL3 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs373239913; called by muse, mutect2, varscan2
- ATP10B | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs759026018, COSV58778845; called by muse, mutect2, varscan2
- ATP10B | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.111); catalogued as COSV58778851; called by muse, mutect2, varscan2
- ATP2A2 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57875428; called by muse, mutect2, varscan2
- ATP5F1C | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV59621694; called by muse, mutect2, varscan2
- ATP6AP2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV65797679; called by muse, mutect2, varscan2
- ATP8B3 | c.3799G>A p.G1267S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59542848; called by muse, mutect2, varscan2
- ATP9A | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 48/135 reads (36%) | catalogued as COSV58766683; called by muse, mutect2, varscan2
- ATR | c.2644G>A p.G882R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63386553; called by muse, mutect2, varscan2
- ATR | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV63386559; called by muse, mutect2, varscan2
- AVPR1B | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868925962, COSV100899448, COSV65637750; called by muse, mutect2, varscan2
- AXDND1 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs773212839, COSV62642775; called by muse, mutect2, varscan2
- B3GALT4 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1018901534, COSV65851579; called by muse, mutect2, varscan2
- B3GAT1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.38); catalogued as rs1300211992, COSV56997054; called by muse, mutect2
- B3GNT3 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57953199; called by muse, mutect2, varscan2
- BACH2 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV57590437; called by muse, mutect2, varscan2
- BAG4 | c.1123A>G p.S375G | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1351503289, COSV54860173; called by muse, mutect2, varscan2
- BAHD1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV69083981; called by muse, mutect2, varscan2
- BAIAP2L2 | c.216G>A p.G72= | Splice Region (SNP) | VAF 19/74 reads (26%) | catalogued as COSV59269772; called by muse, mutect2, varscan2
- BCAS3 | c.953T>G p.I318S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66774288; called by muse, mutect2, varscan2
- BCL6B | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773759474, COSV99546715; called by muse, mutect2, varscan2
- BCL9L | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.388); catalogued as rs1316558261, COSV52684424; called by muse, varscan2
- BCO2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764094222, COSV63062697, COSV63064809; called by muse, mutect2, varscan2
- BDP1 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV62431463; called by muse, mutect2, varscan2
- BMP10 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as COSV54894285; called by muse, mutect2, varscan2
- BMP3 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs866813886, COSV51081796; called by muse, mutect2, varscan2
- BMP6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51662298; called by muse, mutect2, varscan2
- BMPR1A | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs1554891677, COSV64406144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 93/143 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV61757455; called by muse, mutect2, varscan2
- BPIFB2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs150536106, COSV50063165; called by muse, mutect2, varscan2
- BPIFB6 | c.578-1G>A p.X193_splice | Splice Site (SNP) | VAF 40/170 reads (24%) | catalogued as COSV62755248; called by muse, mutect2, varscan2
- BRCA2 | c.8111C>T p.S2704F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs80359054, CM011915, COSV66453856; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs112160006, COSV56300186; called by muse, mutect2, varscan2
- BSN | c.7849G>A p.E2617K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs375612033; called by muse, mutect2, varscan2
- BTNL3 | c.1184T>G p.F395C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1171879416, COSV61564889; called by muse, mutect2, varscan2
- C11orf54 | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58680485; called by muse, mutect2, varscan2
- C17orf97 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.031); catalogued as COSV64076529; called by muse, mutect2, varscan2
- C1QTNF9B | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781326209, COSV65944133; called by muse, mutect2, varscan2
- C1orf116 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs372329519, COSV63944075; called by muse, mutect2, varscan2
- C1orf87 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV64597145; called by muse, mutect2, varscan2
- C1orf87 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs1359540097, COSV64597149; called by muse, mutect2, varscan2
- C22orf42 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.198); catalogued as rs151297448; called by muse, mutect2, varscan2
- C2orf66 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61098868; called by muse, mutect2, varscan2
- C2orf78 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.779); catalogued as COSV68517564; called by muse, mutect2, varscan2
- C3 | c.1845+1G>A p.X615_splice | Splice Site (SNP) | VAF 61/245 reads (25%) | catalogued as rs111861067, COSV55573173; called by muse, mutect2, varscan2
- C4BPA | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs780844313, COSV65536420; called by muse, mutect2, varscan2
- C4orf50 | c.700C>T p.Q234* (on ENST00000324058; = p.Q1466* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV60688647; called by muse, mutect2, varscan2
- C6 | c.2675G>A p.G892E | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99667340; called by muse, mutect2, varscan2
- C6 | c.2674G>A p.G892R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.319); catalogued as COSV54704935; called by muse, mutect2, varscan2
- C6orf118 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs199710080, COSV57812764; called by muse, varscan2
- C6orf58 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1303343348, COSV61666548; called by muse, mutect2, varscan2
- C8B | c.1280T>G p.V427G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64777681; called by muse, mutect2, varscan2
- C8orf34 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61378113, COSV61380370; called by muse, mutect2, varscan2
- C9orf135 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV65875455; called by muse, mutect2, varscan2
- CA11 | c.472-1G>A p.X158_splice | Splice Site (SNP) | VAF 18/83 reads (22%) | catalogued as rs1271196751, COSV50033052; called by muse, mutect2, varscan2
- CA3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); catalogued as COSV53409923; called by muse, mutect2, varscan2
- CABIN1 | c.4877C>T p.S1626F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs980608769, COSV54081831; called by muse, mutect2, varscan2
- CACNA1C | c.6079C>T p.P2027S (on ENST00000399634 / NM_001167625.1; = p.P1956S on NM_000719.7) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59719871; called by muse, mutect2, varscan2
- CACNA1I | c.5854G>A p.D1952N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.164); catalogued as COSV60808661; called by muse, mutect2, varscan2
- CACNA1S | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62939603; called by muse, mutect2, varscan2
- CACNA2D3 | c.2960G>A p.G987E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV55539709, COSV99875993; called by muse, mutect2, varscan2
- CACNG5 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV50055843; called by muse, mutect2, varscan2
- CADM2 | c.713C>T p.P238L (on ENST00000407528 / NM_001167674.2; = p.P240L on NM_153184.4) | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67375253; called by muse, mutect2, varscan2
- CADM3 | c.940C>T p.L314F (on ENST00000368125 / NM_001127173.3; = p.L348F on NM_021189.5) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63685514; called by muse, mutect2
- CADPS | c.3475G>T p.E1159* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99339173; called by mutect2, varscan2
- CADPS | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51880444; called by muse, mutect2, varscan2
- CALCRL | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66474952; called by muse, mutect2
- CALML3 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV59449378; called by muse, mutect2
- CAMK2D | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV56430658; called by muse, mutect2, varscan2
- CAMTA1 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57901436; called by muse, mutect2, varscan2
- CAPN1 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs777787068, COSV54198672; called by mutect2, varscan2
- CAPN11 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291904; called by muse, mutect2, varscan2
- CARF | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 130/411 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV57547684; called by muse, mutect2, varscan2
- CASP14 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs936540103, COSV55664718; called by muse, mutect2, varscan2
- CASP5 | c.509A>T p.E170V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV52828618; called by muse, mutect2, varscan2
- CASQ2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.821); catalogued as COSV54770533; called by muse, mutect2, varscan2
- CATSPERE | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs1241277755, COSV63678010; called by muse, mutect2, varscan2
- CATSPERG | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs147603617; called by muse, mutect2, varscan2
- CATSPERG | c.3002A>T p.H1001L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.39); catalogued as COSV53048827; called by muse, mutect2, varscan2
- CATSPERG | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as COSV53048847; called by muse, mutect2, varscan2
- CBFA2T3 | c.1206C>T p.L402= | Splice Region (SNP) | VAF 13/24 reads (54%) | catalogued as COSV51927081; called by muse, mutect2, varscan2
- CBLC | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54322658; called by muse, mutect2, varscan2
- CCDC110 | c.595A>T p.N199Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV56870960; called by muse, mutect2, varscan2
- CCDC148 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV51760609; called by muse, mutect2, varscan2
- CCDC150 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV55874421; called by mutect2, varscan2
- CCDC40 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV66474823; called by muse, mutect2, varscan2
- CCDC57 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747068516, COSV66434006; called by muse, mutect2, varscan2
- CCDC68 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV61603690; called by muse, mutect2, varscan2
- CCDC81 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as rs1326084006, COSV53578394; called by muse, mutect2, varscan2
- CCDC85A | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68150882; called by muse, mutect2, varscan2
- CCDC87 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59579131; called by muse, mutect2, varscan2
- CCDC88B | c.2137G>A p.G713S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV57266210; called by muse, mutect2, varscan2
- CCR4 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV58381407; called by muse, mutect2, varscan2
- CD177 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV65121346; called by muse, mutect2, varscan2
- CD180 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV56517021; called by muse, mutect2, varscan2
- CD1C | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs780763972, COSV63806482; called by muse, mutect2, varscan2
- CD1E | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63771001; called by muse, mutect2, varscan2
- CD200R1 | c.159G>A p.M53I (on ENST00000471858 / NM_170780.3; = p.M76I on NM_138806.4) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55600844; called by muse, mutect2, varscan2
- CD300LG | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV53223169; called by muse, mutect2, varscan2
- CD52 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.974); catalogued as COSV57485972; called by muse, mutect2, varscan2
- CDCP1 | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56105504; called by muse, mutect2, varscan2
- CDH10 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.13); catalogued as rs200377194, COSV100050894, COSV52581136, COSV52592268; called by muse, mutect2, varscan2
- CDH18 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56923089; called by muse, mutect2, varscan2
- CDH4 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64655025; called by muse, mutect2, varscan2
- CDHR2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56138875; called by muse, mutect2, varscan2
- CDPF1 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1232967321, COSV53078631; called by muse, mutect2, varscan2
- CEACAM18 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568524029, COSV67282930, COSV67283059; called by muse, mutect2, varscan2
- CEBPE | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1376968968, COSV52829780; called by muse, mutect2, varscan2
- CELA2B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65545630; called by muse, mutect2, varscan2
- CENPF | c.2047C>T p.H683Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV65275050; called by muse, mutect2, varscan2
- CENPI | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1428236562, COSV54501883; called by muse, mutect2, varscan2
- CEP126 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54821704; called by muse, mutect2, varscan2
- CEP162 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1478932859, COSV57619993; called by muse, mutect2, varscan2
- CEP250 | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV61170181; called by muse, mutect2, varscan2
- CEP350 | c.5293A>T p.K1765* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV62602670; called by muse, mutect2, varscan2
- CEP68 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV53124975; called by muse, mutect2, varscan2
- CEP70 | c.1119A>T p.K373N | Missense Mutation (SNP) | VAF 155/510 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV53875737; called by muse, mutect2, varscan2
- CERS3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs770299041, COSV52568688; called by muse, mutect2, varscan2
- CFAP43 | c.3473G>A p.R1158K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as COSV63853150; called by muse, mutect2, varscan2
- CFAP44 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV55611485; called by muse, mutect2, varscan2
- CFAP58 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57212162; called by muse, mutect2, varscan2
- CFAP65 | c.4691C>A p.T1564K | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV58561048; called by muse, mutect2, varscan2
- CFAP74 | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774046284, COSV60587073; called by muse, mutect2, varscan2
- CFAP94 | c.1415C>T p.S472F (on ENST00000320267 / NM_001352064.2; = p.S478F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as COSV57232285; called by muse, varscan2
- CFTR | c.3934G>A p.D1312N | Missense Mutation (SNP) | VAF 94/137 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50053957; called by muse, mutect2, varscan2
- CGAS | c.727T>A p.S243T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.297); catalogued as COSV64808179; called by muse, mutect2, varscan2
- CHAF1B | c.1079T>G p.F360C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58440136; called by muse, mutect2, varscan2
- CHD3 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1178138055, COSV57875109; called by muse, mutect2, varscan2
- CHD4 | c.5414T>C p.M1805T (on ENST00000357008 / NM_001363606.2; = p.M1816T on NM_001273.5) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV58901370; called by muse, mutect2, varscan2
- CHD5 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1451298100, COSV52414798; called by muse, mutect2, varscan2
- CHD8 | c.4442C>T p.T1481I (on ENST00000646647 / NM_001170629.2; = p.T1202I on NM_020920.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV63219137; called by muse, mutect2, varscan2
- CHFR | c.764C>T p.P255L (on ENST00000432561 / NM_001161345.1; = p.P214L on NM_018223.2) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762481129, COSV99905432; called by muse, mutect2, varscan2
- CHST12 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV51675128; called by muse, mutect2, varscan2
- CKMT1A | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs754073482, COSV100787705; called by muse, mutect2, varscan2
- CLCN6 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs778798005, COSV56740193; called by muse, mutect2, varscan2
- CLEC18B | c.1284G>A p.W428* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV60577545; called by muse, mutect2, varscan2
- CLGN | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57773422; called by muse, mutect2, varscan2
- CLNK | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57015093; called by muse, mutect2
- CLTC | c.4270A>G p.M1424V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52247852; called by muse, mutect2, varscan2
- CNGA2 | c.392T>C p.F131S | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs764964759, COSV61704544; called by muse, mutect2, varscan2
- CNGB1 | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs756942679, COSV51900934, COSV51902161; called by muse, mutect2, varscan2
- CNR1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV62987339, COSV62987433; called by muse, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, mutect2, varscan2
- CNTNAP4 | c.2819T>A p.M940K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV56680898; called by muse, mutect2, varscan2
- CNTNAP5 | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 55/183 reads (30%) | catalogued as rs768209651, COSV70475052; called by muse, mutect2, varscan2
- COBLL1 | c.2462C>T p.S821L (on ENST00000392717; = p.S783L on NM_014900.5) | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773360766, COSV52067939; called by muse, mutect2, varscan2
- COL11A1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62183880; called by muse, mutect2, varscan2
- COL17A1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV62226411, COSV62226774; called by muse, varscan2
- COL1A1 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs373474549, COSV56805168; called by muse, mutect2, varscan2
- COL1A1 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV56805013; called by muse, varscan2
- COL20A1 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs543389947, COSV58917341; called by muse, mutect2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by muse, varscan2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, varscan2
- COL3A1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV58588017; called by muse, mutect2, varscan2
- COL4A1 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV65425827; called by mutect2, varscan2
- COL4A1 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs1468687240, COSV65425834; called by muse, mutect2, varscan2
- COL4A4 | c.3688G>A p.G1230S | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781360383, COSV61632273; called by muse, mutect2, varscan2
- COL4A4 | c.2987G>A p.G996E | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61638268; called by muse, mutect2, varscan2
- COL4A5 | c.1071A>T p.E357D | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as COSV60361793; called by muse, mutect2, varscan2
- COL6A3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV55089756; called by muse, varscan2
- COL6A6 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62025448; called by muse, mutect2, varscan2
- COL7A1 | c.6019G>A p.D2007N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as rs757972415, COSV60395386; called by mutect2, varscan2
- COL8A1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV53734654; called by muse, mutect2, varscan2
- COLEC12 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV68370666; called by muse, mutect2, varscan2
- COQ5 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as COSV56019074; called by muse, mutect2
- COX6C | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52553775; called by muse, mutect2, varscan2
- CP | c.2591G>A p.R864K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV52830720; called by muse, mutect2, varscan2
- CPA3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV56045176, COSV99936388; called by muse, mutect2, varscan2
- CPA3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199600994, COSV56044010; called by muse, mutect2, varscan2
- CPEB4 | c.1194T>G p.N398K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV54171760; called by muse, mutect2, varscan2
- CPN2 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60470453; called by muse, mutect2, varscan2
- CPNE5 | c.1135T>C p.F379L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs773282449, COSV55196576; called by muse, mutect2, varscan2
- CR1L | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54323619; called by muse, mutect2, varscan2
- CREB3L4 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1279943650, COSV55132134; called by muse, mutect2, varscan2
- CREB3L4 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55132136; called by muse, mutect2, varscan2
- CRISP3 | c.361C>T p.R121* (on ENST00000371159 / NM_001368123.1; = p.R103* on NM_006061.4) | Nonsense Mutation (SNP) | VAF 34/170 reads (20%) | catalogued as rs1256803148, COSV53820373; called by muse, mutect2, varscan2
- CRLF1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1366378385, COSV66504562; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1400757152, COSV53232441; called by muse, mutect2
- CSF1 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV60033087; called by muse, mutect2, varscan2
- CSMD1 | c.1151G>A p.G384E (on ENST00000520002; = p.G383E on NM_033225.6) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68205656; called by muse, mutect2, varscan2
- CSMD2 | c.10226G>A p.S3409N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV53913154; called by muse, mutect2, varscan2
- CSMD2 | c.5176+2T>A p.X1726_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53913182; called by muse, mutect2, varscan2
- CSMD3 | c.10670A>C p.Y3557S (on ENST00000297405 / NM_001363185.1; = p.Y3388S on NM_052900.3) | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV52184131; called by muse, mutect2, varscan2
- CSMD3 | c.9299G>A p.G3100D (on ENST00000297405 / NM_001363185.1; = p.G2931D on NM_052900.3) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52184151; called by muse, mutect2, varscan2
- CSMD3 | c.1660G>C p.G554R (on ENST00000297405 / NM_001363185.1; = p.G450R on NM_052900.3) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52184164, COSV52199056; called by muse, mutect2, varscan2
- CSMD3 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52184184, COSV52216363; called by muse, mutect2, varscan2
- CSNK1G3 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV62054676; called by muse, mutect2, varscan2
- CSRP2 | c.411+2T>A p.X137_splice | Splice Site (SNP) | VAF 19/44 reads (43%) | catalogued as COSV60702120, COSV60702632; called by muse, mutect2, varscan2
- CST8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.398); catalogued as COSV55671151; called by muse, mutect2, varscan2
- CTDNEP1 | c.350T>G p.F117C | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56641980; called by muse, mutect2, varscan2
- CTH | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100697068, COSV61008513; called by muse, mutect2, varscan2
- CTIF | c.1036T>A p.S346T | Missense Mutation (SNP) | VAF 131/361 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV56483946; called by muse, mutect2, varscan2
- CTRC | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1188160137, COSV65621483; called by muse, mutect2, varscan2
- CUBN | c.5903G>A p.G1968D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs778249964, COSV64716019; called by muse, mutect2, varscan2
- CUBN | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64716024; called by muse, mutect2, varscan2
- CUX1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 118/154 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781879428, COSV52899988; called by muse, mutect2, varscan2
- CUX1 | c.2861A>G p.E954G | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52900003; called by muse, mutect2, varscan2
- CUX1 | c.3742C>T p.R1248W | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52899602; called by muse, varscan2
- CWC27 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66885878; called by muse, mutect2, varscan2
- CWH43 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV56938999; called by muse, mutect2, varscan2
- CX3CR1 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV64193939; called by muse, mutect2, varscan2
- CXCR1 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV55281938; called by muse, mutect2, varscan2
- CYFIP2 | c.2680C>T p.P894S (on ENST00000616178 / NM_001291722.2; = p.P869S on NM_014376.4) | Missense Mutation (SNP) | VAF 168/573 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV56636716; called by muse, mutect2, varscan2
- CYP2B6 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as rs1485333607, COSV57843772; called by muse, mutect2, varscan2
- CYP2C18 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV53672291; called by muse, mutect2, varscan2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2, varscan2
- CYP2C8 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs551515028, COSV100988040, COSV64876314; called by muse, mutect2, varscan2
- CYP39A1 | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as COSV99242434; called by muse, mutect2, varscan2
- CYP39A1 | c.658A>T p.K220* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV99242437; called by muse, mutect2, varscan2
- CYP4A11 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV60223566; called by muse, varscan2
- CYP4A22 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53740239; called by muse, mutect2, varscan2
- CYP4F12 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374175073; called by muse, mutect2, varscan2
- CYP4F2 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55618077; called by muse, mutect2
- CYP4F2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs772862283, COSV55618090; called by muse, mutect2, varscan2
- CYP4F3 | c.648G>A p.E216= | Splice Region (SNP) | VAF 61/209 reads (29%) | catalogued as COSV55409959; called by muse, mutect2, varscan2
- CYP4F3 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771683799, COSV55409980; called by muse, mutect2
- CYP4X1 | c.1246A>C p.N416H | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV64150730; called by muse, mutect2, varscan2
- CYRIA | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62865187; called by muse, mutect2, varscan2
- CYSLTR1 | c.637A>C p.I213L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV64820184; called by muse, mutect2, varscan2
- DAAM1 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62836359; called by muse, mutect2, varscan2
- DCAF16 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.231); catalogued as rs979777525, COSV66384203; called by muse, varscan2
- DCAF6 | c.292T>G p.F98V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56578838; called by muse, mutect2, varscan2
- DCC | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV59103256; called by muse, mutect2, varscan2
- DCLK1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV55187100; called by muse, mutect2, varscan2
- DCUN1D1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV53044422; called by muse, mutect2, varscan2
- DDIAS | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs779312498, COSV61272161; called by mutect2, varscan2
- DDX3X | c.1582A>C p.I528L (on ENST00000399959; = p.I529L on NM_001356.5) | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67863027; called by muse, mutect2, varscan2
- DDX46 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as rs1187045828, COSV62799368; called by muse, mutect2, varscan2
- DDX51 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57958223; called by muse, mutect2, varscan2
- DENND3 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV52802434; called by muse, mutect2, varscan2
- DERL2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 28/178 reads (16%) | catalogued as COSV99342379; called by muse, mutect2, varscan2
- DGKG | c.2171A>C p.K724T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV53965350; called by muse, mutect2, varscan2
- DHRS7C | c.278C>T p.T93I (on ENST00000330255 / NM_001220493.2; = p.T92I on NM_001105571.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1415605810, COSV100364819, COSV57650808; called by muse, mutect2, varscan2
- DHTKD1 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 152/466 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53803695; called by muse, mutect2, varscan2
- DHX16 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as rs750449295, COSV64580650; called by muse, mutect2, varscan2
- DIP2C | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs929778146, COSV55158552; called by muse, mutect2, varscan2
- DIP2C | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV99792327; called by muse, mutect2, varscan2
- DIS3 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV66706465; called by muse, mutect2, varscan2
- DISP1 | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 155/456 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52659054, COSV99450206; called by muse, mutect2, varscan2
- DLEC1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs900965895, COSV57299860; called by muse, mutect2, varscan2
- DLGAP1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); catalogued as COSV59804587; called by muse, mutect2, varscan2
- DMBT1 | c.4927G>A p.G1643R (on ENST00000338354 / NM_001377530.1; = p.G886R on NM_004406.3) | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57543999; called by muse, mutect2, varscan2
- DMWD | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52178409; called by muse, mutect2, varscan2
- DMXL2 | c.7208C>T p.S2403L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV51846688; called by muse, varscan2
- DMXL2 | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.136); catalogued as COSV51846696; called by muse, mutect2, varscan2
- DNAH1 | c.9257A>C p.D3086A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV70229103; called by muse, mutect2
- DNAH10 | c.1372G>A p.E458K (on ENST00000409039; = p.E397K on NM_207437.3) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV68993936; called by muse, mutect2, varscan2
- DNAH10 | c.3421G>A p.E1141K (on ENST00000409039; = p.E1080K on NM_207437.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV101292348, COSV69004548; called by muse, mutect2, varscan2
- DNAH10 | c.3961G>A p.E1321K (on ENST00000409039; = p.E1260K on NM_207437.3) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV68993943; called by muse, varscan2
- DNAH10 | c.4261G>A p.E1421K (on ENST00000409039; = p.E1360K on NM_207437.3) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV68993948; called by muse, mutect2, varscan2
- DNAH17 | c.5051G>A p.R1684K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV101102697; called by muse, mutect2
- DNAH17 | c.3682G>A p.D1228N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.175); catalogued as rs767607925, COSV67751014; called by muse, mutect2, varscan2
- DNAH3 | c.12106G>A p.E4036K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54522064; called by muse, mutect2, varscan2
- DNAH3 | c.9709G>A p.E3237K | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54512537; called by muse, mutect2, varscan2
- DNAH5 | c.12390G>A p.M4130I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1474585287, COSV54225246; called by muse, mutect2, varscan2
- DNAH5 | c.12083T>G p.V4028G | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54225259; called by muse, mutect2, varscan2
- DNAH5 | c.9832G>A p.A3278T | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV54225281; called by muse, mutect2, varscan2
- DNAH5 | c.9460G>A p.D3154N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV54208781; called by muse, mutect2, varscan2
- DNAH5 | c.7373G>A p.S2458N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV54225303; called by muse, mutect2, varscan2
- DNAH5 | c.4205T>A p.L1402H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54225319; called by muse, mutect2, varscan2
- DNAH5 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54217167; called by muse, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, varscan2
- DNAH5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs116128702, COSV54201708; ClinVar: uncertain significance; called by muse, varscan2
- DNAH7 | c.10195G>A p.E3399K | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV56765367; called by muse, mutect2, varscan2
- DNAH7 | c.6358G>A p.D2120N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV56751887; called by muse, mutect2, varscan2
- DNAH7 | c.4091G>A p.G1364E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751541338, COSV56756184; called by muse, mutect2, varscan2
- DNAH7 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100413748, COSV56765389; called by muse, mutect2, varscan2
- DNAH8 | c.12999T>A p.F4333L | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.364); catalogued as COSV59445994; called by muse, mutect2, varscan2
- DNAH9 | c.4341G>A p.M1447I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1396750693, COSV52350000; called by muse, mutect2, varscan2
- DNAH9 | c.7234C>T p.P2412S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52350008; called by muse, mutect2, varscan2
- DNAH9 | c.11815G>A p.E3939K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350024, COSV99305877; called by muse, mutect2, varscan2
- DNAJC16 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769958348, COSV101012606; called by muse, mutect2, varscan2
- DNAJC6 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867510079, COSV54775051; called by muse, mutect2, varscan2
- DNASE2 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53435051; called by muse, mutect2, varscan2
- DNHD1 | c.12277C>T p.P4093S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54442899, COSV99600380; called by muse, mutect2, varscan2
- DNMBP | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as COSV60625277; called by muse, mutect2, varscan2
- DOCK8 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV66634060; called by muse, mutect2, varscan2
- DOCK9 | c.1846C>T p.P616S (on ENST00000376460 / NM_001366676.2; = p.P617S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV59626499; called by muse, mutect2, varscan2
- DOK7 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60772204; called by muse, mutect2, varscan2
- DPP10 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59686682; called by muse, mutect2, varscan2
- DPP10 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59687022; called by muse, mutect2, varscan2
- DPP4 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs201511821, COSV62106796; called by muse, mutect2, varscan2
- DPY19L3 | c.401T>G p.I134S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV60476876; called by muse, mutect2, varscan2
- DPYS | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs751818026, COSV60907008; called by muse, mutect2, varscan2
- DSC3 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV64571819, COSV64573553; called by muse, mutect2, varscan2
- DSCAM | c.5423C>T p.S1808F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68026866; called by muse, mutect2, varscan2
- DSE | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1213311228, COSV59064055; called by muse, mutect2, varscan2
- DSG1 | c.858T>A p.N286K | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs761869585, COSV57135391; called by muse, mutect2, varscan2
- DSG2 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as rs1188569362, COSV55199240; called by muse, mutect2, varscan2
- DSG4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV57391797; called by muse, mutect2, varscan2
- DSP | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV65792824; called by muse, mutect2, varscan2
- DSP | c.8567C>G p.S2856C | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV60939479, COSV60940167; called by muse, mutect2, varscan2
- DST | c.4408C>T p.P1470S (on ENST00000361203 / NM_001374722.1; = p.P1144S on NM_015548.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV55015023; called by muse, mutect2, varscan2
- DTX3L | c.2162A>C p.Y721S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56144170; called by muse, mutect2, varscan2
- DUSP7 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV56589056; called by muse, mutect2, varscan2
- E2F3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 172/508 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV60896053; called by muse, mutect2, varscan2
- ECPAS | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52197379; called by muse, mutect2, varscan2
- ECT2L | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV62884525; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV62567921; called by muse, mutect2, varscan2
- EFNB3 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs972550180, COSV56833479; called by muse, mutect2
- EFR3A | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764376469, COSV54457442; called by muse, mutect2, varscan2
- EGFLAM | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.785); catalogued as COSV100380428; called by muse, mutect2, varscan2
- EHBP1 | c.2116A>C p.K706Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.23); catalogued as COSV50420461; called by muse, mutect2, varscan2
- EHD3 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100434766; called by muse, mutect2, varscan2
- ELF5 | c.646G>A p.G216R (on ENST00000312319 / NM_198381.2; = p.G206R on NM_001422.4) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56628956; called by muse, mutect2, varscan2
- ELOVL4 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV63953905; called by muse, mutect2, varscan2
- EMB | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV57482268, COSV57485869; called by muse, mutect2, varscan2
- EMID1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV61829469; called by muse, mutect2, varscan2
- ENAM | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs372577583, COSV68535979; called by muse, mutect2, varscan2
- ENDOD1 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.758); catalogued as COSV53589140; called by muse, mutect2, varscan2
- ENTPD3 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088803; called by muse, mutect2, varscan2
- EPB41 | c.836C>T p.P279L (on ENST00000343067 / NM_001166005.2; = p.P70L on NM_004437.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV58046852; called by muse, mutect2, varscan2
- EPB41L4A | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV54869839; called by muse, mutect2, varscan2
- EPHA7 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV65182887; called by muse, mutect2, varscan2
- EPS15 | c.2141T>A p.V714D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100869563; called by muse, mutect2, varscan2
- ERBB2 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV54070762; called by muse, mutect2, varscan2
- ERG | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV55732239; called by muse, mutect2, varscan2
- ERP44 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs746106972, COSV52431740; called by muse, mutect2, varscan2
- ESRRB | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.911); catalogued as COSV55059780; called by muse, mutect2, varscan2
- ETNPPL | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1034727796, COSV56595821; called by muse, mutect2, varscan2
- ETV4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769333020, COSV60044338; called by muse, mutect2, varscan2
- EVPL | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.661); catalogued as COSV56911043; called by muse, mutect2
- EXPH5 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV56202424; called by muse, mutect2, varscan2
- EXTL1 | c.1855G>A p.G619R | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100958568; called by muse, mutect2, varscan2
- EXTL1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV65332858; called by muse, mutect2, varscan2
- EXTL3 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55038048; called by muse, mutect2, varscan2
- EXTL3 | c.1960C>T p.L654F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55038057; called by muse, mutect2, varscan2
- F2RL1 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 213/699 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995749; called by muse, mutect2, varscan2
- F8 | c.5747G>A p.R1916K | Missense Mutation (SNP) | VAF 98/169 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV64273599; called by muse, mutect2, varscan2
- FAAP100 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV59885397; called by muse, varscan2
- FABP1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55558534; called by muse, mutect2, varscan2
- FAM160B1 | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV65088151; called by muse, mutect2
- FAM170A | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV58925249; called by muse, mutect2, varscan2
- FAM171A1 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65313899; called by muse, mutect2, varscan2
- FAM171B | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.136); catalogued as COSV59003609; called by muse, mutect2, varscan2
- FAM181A | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV50888594; called by muse, mutect2, varscan2
- FAM184A | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs141308759, COSV58851670; called by muse, mutect2, varscan2
- FAM217A | c.902T>G p.I301S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51160124; called by muse, mutect2, varscan2
- FAM83B | c.1380T>A p.N460K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV60922186; called by muse, mutect2, varscan2
- FAM91A1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV58237193; called by muse, mutect2, varscan2
- FANCI | c.2821G>A p.G941R (on ENST00000310775 / NM_001376911.1; = p.G881R on NM_018193.3) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as rs1349031115, COSV55527139; called by muse, varscan2
- FARP1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs780387697, COSV100131062; called by muse, mutect2, varscan2
- FAT1 | c.4381T>A p.Y1461N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392940143, COSV71673979; called by muse, mutect2, varscan2
- FAT2 | c.4399C>T p.L1467F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV55819890; called by muse, mutect2, varscan2
- FAT3 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 172/547 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53111526; called by muse, mutect2, varscan2
- FAT3 | c.3322C>T p.R1108W | Missense Mutation (SNP) | VAF 135/401 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs368324627, COSV53111539; called by muse, mutect2, varscan2
- FAT3 | c.8317C>T p.R2773C | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs780613312, COSV53111551, COSV53127574; called by muse, varscan2
- FAT4 | c.2431C>T p.H811Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.45); catalogued as rs1307860920, COSV67886885; called by muse, mutect2, varscan2
- FAT4 | c.6601G>A p.E2201K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs866400807, COSV58674112; called by muse, mutect2, varscan2
- FBF1 | c.2956G>A p.E986K (on ENST00000586717; = p.E1001K on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100045147, COSV100045306; called by muse, mutect2, varscan2
- FBN3 | c.4180G>T p.D1394Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV104374124, COSV99561214; called by muse, mutect2, varscan2
- FBXO4 | c.1163G>T p.*388Lext*12 | Nonstop Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV55852221; called by muse, mutect2, varscan2
- FBXO40 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1441822615, COSV57524059; called by muse, mutect2, varscan2
- FCRL5 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62512252; called by muse, varscan2
- FEM1A | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1231021963, COSV54163885; called by muse, mutect2, varscan2
- FER1L6 | c.2804T>A p.L935* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV67549960; called by muse, mutect2, varscan2
- FER1L6 | c.4436T>A p.I1479N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV67549964; called by muse, mutect2, varscan2
- FGA | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.875); catalogued as rs1251079190, COSV57396136; called by muse, mutect2, varscan2
- FGA | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57396146; called by muse, mutect2, varscan2
- FGA | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV57396172, COSV57402083; called by muse, mutect2, varscan2
- FGF16 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV71546185; called by muse, mutect2, varscan2
- FGF7 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51066118; called by muse, mutect2, varscan2
- FGFBP1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV52586498; called by muse, mutect2, varscan2
- FGGY | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs772540010, COSV58027195; called by muse, mutect2, varscan2
- FGGY | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs560935352, COSV58033364; called by muse, mutect2, varscan2
- FGR | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV64969435; called by muse, mutect2, varscan2
- FIP1L1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV60996542; called by muse, mutect2, varscan2
- FLG2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV66166901; called by muse, mutect2, varscan2
- FLG2 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as rs139597182; called by muse, mutect2, varscan2
- FLG2 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV101165960; called by muse, mutect2, varscan2
- FLNC | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766023596, COSV57955983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT1 | c.943T>C p.S315P | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV64508384; called by muse, mutect2
- FLT1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV56728011; called by muse, mutect2
- FLVCR1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768682438, COSV65323579; called by muse, mutect2, varscan2
- FMN2 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779310703, COSV60422534, COSV60455849; called by muse, mutect2
- FMO3 | c.374G>A p.W125* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV63007254; called by muse, mutect2, varscan2
- FMO3 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV63007262; called by muse, varscan2
- FOCAD | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV58098723, COSV58099204; called by muse, mutect2, varscan2
- FOLH1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV57046969; called by muse, mutect2, varscan2
- FOXA3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.321); catalogued as COSV56216034; called by muse, mutect2, varscan2
- FOXR2 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as rs1014381155, COSV59258492; called by muse, varscan2
- FRMD1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as rs201421071, COSV51961851; called by muse, mutect2, varscan2
- FRMD5 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV68722054; called by muse, mutect2, varscan2
- FRYL | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977300; called by muse, varscan2
- FSTL5 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60181228, COSV60186932; called by muse, mutect2, varscan2
- FYB2 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs768309203, COSV58582905, COSV58583687; called by muse, mutect2, varscan2
- FYCO1 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV56116010; called by muse, mutect2, varscan2
- GABRA4 | c.1616T>C p.V539A | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.651); catalogued as COSV51927999; called by muse, mutect2
- GABRB1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV54971566, COSV54996280; called by muse, mutect2, varscan2
- GAD1 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64025908; called by muse, mutect2, varscan2
- GALNT10 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1455800951, COSV51726789; called by muse, mutect2, varscan2
- GALNT2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV64194896; called by muse, mutect2, varscan2
- GALNT8 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV52897457; called by muse, mutect2, varscan2
- GALNT8 | c.979T>C p.F327L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52897464; called by muse, mutect2, varscan2
- GANC | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | PolyPhen probably damaging (0.967); catalogued as COSV58808983; called by muse, mutect2, varscan2
- GANC | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | PolyPhen benign (0); catalogued as COSV58808990; called by muse, mutect2, varscan2
- GAR1 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.92); catalogued as COSV56993338; called by muse, mutect2, varscan2
- GARRE1 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs138673599; called by muse, mutect2, varscan2
- GBP7 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs753882110, COSV54009699; called by muse, varscan2
- GBX1 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV52547617; called by muse, mutect2, varscan2
- GC | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV56736734; called by muse, mutect2, varscan2
- GCKR | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs1245416906, COSV53021227; called by muse, mutect2, varscan2
- GCM1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV52521913; called by muse, mutect2, varscan2
- GCN1 | c.5687C>T p.T1896I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV56104614; called by muse, mutect2, varscan2
- GDNF | c.358T>G p.L120V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58479602; called by muse, mutect2, varscan2
- GIGYF2 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV65245870; called by muse, mutect2, varscan2
- GIP | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs779990019, COSV62467239; called by muse, mutect2, varscan2
- GJA10 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as COSV65355217; called by muse, mutect2, varscan2
- GK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1321996211, COSV62626188; called by muse, mutect2, varscan2
- GLI1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV57357951; called by muse, mutect2, varscan2
- GLIPR1L2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0.148); catalogued as COSV57554182; called by muse, mutect2, varscan2
- GLYATL1 | c.226C>T p.R76C (on ENST00000317391 / NM_001354699.1; = p.R107C on NM_080661.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs151204927, COSV55607318; called by mutect2, varscan2
- GLYATL1 | c.749G>A p.R250Q (on ENST00000317391 / NM_001354699.1; = p.R281Q on NM_080661.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs145479301; called by muse, mutect2, varscan2
- GLYATL2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.198); catalogued as COSV54849326; called by muse, mutect2, varscan2
- GMDS | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as COSV66414172; called by muse, mutect2, varscan2
- GNL1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs139361425; called by muse, mutect2, varscan2
- GOLGA6A | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 27/339 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV51805123; called by muse, mutect2
- GON4L | c.6401C>T p.A2134V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV55193722; called by muse, mutect2, varscan2
- GPA33 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs759768736, COSV63300878; called by mutect2, varscan2
- GPATCH2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65127741; called by muse, mutect2, varscan2
- GPC5 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65599455; called by muse, mutect2, varscan2
- GPC6 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as rs956676538, COSV65512280; called by muse, mutect2, varscan2
- GPLD1 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57757128; called by muse, varscan2
- GPN1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1415858850, COSV53114795; called by muse, mutect2, varscan2
- GPR15 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200700815, COSV52520567; called by muse, mutect2, varscan2
- GPR158 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs371356903; called by muse, mutect2, varscan2
- GPR174 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs770105674, COSV52132582, COSV52134336; called by muse, mutect2, varscan2
- GPR179 | c.1169C>T p.A390V (on ENST00000621958; = p.A389V on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as rs752548157; called by muse, mutect2, varscan2
- GPR179 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as rs1459069832; called by muse, mutect2, varscan2
- GPR18 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV61621226; called by muse, mutect2, varscan2
- GPR39 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as rs1289600237, COSV61416511; called by muse, mutect2, varscan2
- GPRASP2 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs762327307, COSV59990813; called by muse, mutect2, varscan2
- GPRIN2 | c.968C>G p.A323G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV65401029; called by muse, mutect2, varscan2
- GRIA2 | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV52390873; called by muse, mutect2, varscan2
- GRIN2B | c.3685G>A p.V1229M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV74205450; called by muse, mutect2, varscan2
- GRIP2 | c.740C>T p.S247F (on ENST00000619221; = p.S150F on NM_001080423.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as COSV56121468; called by muse, mutect2, varscan2
- GRK7 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53822990; called by muse, mutect2, varscan2
- GRM5 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.076); catalogued as COSV59605487, COSV59616988; called by muse, mutect2, varscan2
- GSTM5 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV56658132; called by muse, mutect2, varscan2
- GSTM5 | c.363G>A p.E121= | Splice Region (SNP) | VAF 26/65 reads (40%) | catalogued as COSV56657191, COSV56658157; called by muse, mutect2, varscan2
- GTF2E1 | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV52204305; called by muse, mutect2, varscan2
- GTF2F1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV66725880; called by muse, mutect2, varscan2
- GTSF1 | c.13T>C p.Y5H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV59938700; called by muse, mutect2, varscan2
- GUCY1A2 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.446); catalogued as COSV56483631; called by muse, mutect2, varscan2
- GUCY2F | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54302086; called by muse, mutect2, varscan2
- GYPB | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as rs757106926, COSV51621678; called by mutect2, varscan2
- H2AC15 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs753465036, COSV57585657; called by muse, mutect2, varscan2
- H3C2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2, varscan2
- H3C8 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV59953862; called by muse, mutect2, varscan2
- HAUS1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs781543549, COSV56363362; called by muse, mutect2, varscan2
- HAUS1 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV56363368; called by muse, mutect2, varscan2
- HCN1 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as rs199774910, COSV57500212; called by muse, mutect2, varscan2
- HCN4 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893466779, COSV56083632; called by muse, mutect2, varscan2
- HDAC9 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67769639; called by muse, mutect2, varscan2
- HEATR5B | c.4960C>T p.P1654S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778722074, COSV51852820; called by muse, mutect2
- HEATR5B | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599367, COSV51848925; called by muse, mutect2, varscan2
- HEATR6 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV51745807; called by muse, mutect2, varscan2
- HECW1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1562982163, COSV67829733; called by muse, mutect2, varscan2
- HECW1 | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV67829741; called by muse, mutect2, varscan2
- HELQ | c.2596C>T p.L866F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV55025285; called by muse, mutect2, varscan2
- HEPH | c.2755C>T p.R919W (on ENST00000343002; = p.R652W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs751730413, COSV57964161; called by muse, mutect2, varscan2
- HGD | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553721599, COSV52198223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIPL2 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58565242; called by muse, mutect2, varscan2
- HIVEP1 | c.5800C>T p.P1934S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65101493; called by muse, mutect2, varscan2
- HIVEP1 | c.6620C>T p.P2207L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV65101500; called by muse, mutect2, varscan2
- HIVEP2 | c.6751C>T p.P2251S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV50013208; called by muse, mutect2, varscan2
- HIVEP2 | c.4969C>T p.P1657S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756008311, COSV50013248; called by muse, mutect2, varscan2
- HMCN1 | c.11623G>A p.E3875K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54901143; called by muse, mutect2, varscan2
- HMCN1 | c.11800G>A p.G3934S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771776707, COSV54901157, COSV99627594; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.440G>A p.R147K (on ENST00000354667 / NM_031243.3; = p.R135K on NM_002137.4) | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV61159086; called by muse, mutect2, varscan2
- HNRNPU | c.1536G>A p.M512I (on ENST00000283179; = p.M574I on NM_004501.3) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV51690065, COSV51691185; called by muse, mutect2, varscan2
- HNRNPU | c.1159C>T p.P387S (on ENST00000283179; = p.P449S on NM_004501.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV51691218; called by muse, mutect2, varscan2
- HOXB2 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.197); catalogued as COSV57486837; called by muse, mutect2, varscan2
- HPS3 | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV56054466; called by muse, mutect2, varscan2
- HS6ST3 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65008949; called by muse, mutect2, varscan2
- HSPA12B | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as rs760812368, COSV54766735; called by muse, mutect2, varscan2
- HSPA6 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.103); catalogued as rs1469763638, COSV59061098; called by muse, mutect2, varscan2
- HSPA8 | c.557A>C p.D186A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57083994; called by muse, mutect2, varscan2
- HSPBAP1 | c.1060A>G p.M354V | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1487482569, COSV60242324; called by muse, varscan2
- HSPBAP1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778387110, COSV60242367; called by muse, varscan2
- HTR1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.077); catalogued as rs1305700771, COSV60500833; called by muse, mutect2, varscan2
- HTR3B | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867246724, COSV52744652; called by muse, mutect2, varscan2
- HTR3C | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as rs765516991, COSV59175333; called by muse, mutect2, varscan2
- HYDIN | c.3766G>A p.D1256N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs763669224, COSV66832183; called by muse, mutect2, varscan2
- IARS2 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56957822; called by muse, mutect2, varscan2
- ICE2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV55030712; called by muse, mutect2, varscan2
- IFIH1 | c.1742G>A p.W581* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55126799; called by muse, mutect2, varscan2
- IFNL3 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs769262568, COSV69829985; called by muse, mutect2, varscan2
- IGF2BP1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV51731447; called by muse, mutect2, varscan2
- IGHG4 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs773942746; called by muse, mutect2, varscan2
- IGHV4-28 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as rs372033739; called by muse, mutect2
- IGIP | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs373649776; called by muse, mutect2, varscan2
- IGSF10 | c.98G>C p.C33S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56785357; called by muse, mutect2, varscan2
- IGSF21 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52127636; called by muse, varscan2
- IGSF21 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV52127932; called by muse, mutect2, varscan2
- IGSF8 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58758067; called by muse, mutect2, varscan2
- IGSF8 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs771772836, COSV58758077; called by muse, mutect2, varscan2
- IGSF9B | c.1286A>T p.E429V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV58067712; called by muse, mutect2, varscan2
- IKZF1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58785849; called by muse, mutect2
- IL1R1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52106190; called by muse, mutect2, varscan2
- IL1RAPL2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV61158083; called by muse, mutect2, varscan2
- IL20RB | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV59047976; called by muse, varscan2
- IL32 | c.701A>T p.K234I (on ENST00000396890 / NM_001308078.4; = p.K188I on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV50404469; called by muse, varscan2
- IL5RA | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV56523293; called by muse, mutect2, varscan2
- ILDR1 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.424); catalogued as COSV99878468; called by muse, mutect2, varscan2
- ILF3 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99139856; called by muse, mutect2, varscan2
- ILF3 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99139862; called by muse, mutect2, varscan2
- INAVA | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs761732608, COSV66256390; called by muse, mutect2, varscan2
- INO80B | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1041548163, COSV51969408; called by muse, mutect2, varscan2
- IPCEF1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54540833; called by muse, mutect2, varscan2
- IQCH | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.35); catalogued as COSV60052948; called by muse, mutect2, varscan2
- IQGAP3 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63251582; called by muse, mutect2, varscan2
- ITGA11 | c.2788G>A p.G930S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs1333421141, COSV59877742; called by muse, mutect2
- ITGA4 | c.2746C>T p.H916Y | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV67897368; called by muse, mutect2, varscan2
- ITGA7 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs773647967, COSV57691400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAD | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.135); catalogued as COSV54931915, COSV54931975; called by muse, mutect2, varscan2
- ITGB3BP | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52132853, COSV52134397; called by muse, mutect2, varscan2
- ITGB4 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52326018; called by muse, mutect2, varscan2
- ITIH1 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369941533, COSV56252526; called by muse, mutect2, varscan2
- ITIH2 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV64433213; called by muse, mutect2, varscan2
- ITLN1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1444675320, COSV58275151; called by muse, mutect2, varscan2
- ITSN1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs1340587657, COSV66083080; called by muse, mutect2, varscan2
- IYD | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs934484161, COSV99989787; called by muse, mutect2, varscan2
- JARID2 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59189391; called by muse, mutect2, varscan2
- JARID2 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.289); catalogued as COSV59189397; called by muse, mutect2, varscan2
- JARID2 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59189406; called by muse, mutect2, varscan2
- JCAD | c.3652C>T p.H1218Y | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64759668; called by muse, mutect2, varscan2
- JMJD4 | c.1108-1G>A p.X370_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100248277; called by muse, mutect2, varscan2
- JPH4 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV58112613; called by muse, mutect2, varscan2
- JPH4 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV58112617, COSV58113996; called by muse, mutect2, varscan2
- KALRN | c.5008G>A p.G1670R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62566788; called by muse, mutect2, varscan2
- KANK4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.134); catalogued as rs868518757, COSV62986804; called by muse, mutect2, varscan2
- KBTBD8 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1288281483, COSV55128513; called by muse, mutect2, varscan2
- KCNB2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV73050303; called by muse, mutect2, varscan2
- KCNF1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV54463513; called by muse, mutect2, varscan2
- KCNF1 | c.1177T>G p.C393G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54463528; called by muse, mutect2
- KCNH7 | c.1384T>A p.F462I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59797093; called by muse, mutect2, varscan2
- KCNIP1 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV61084602; called by muse, mutect2, varscan2
- KCNIP1 | c.205C>T p.R69* (on ENST00000411494 / NM_001034837.3; = p.R58* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as rs763897144, COSV61080929; called by muse, mutect2, varscan2
- KCNJ1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs757445039, COSV60661835; called by muse, mutect2, varscan2
- KCNJ1 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100131375; called by muse, mutect2, varscan2
- KCNK10 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56640100; called by muse, mutect2, varscan2
- KCNK9 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV57281846; called by muse, mutect2, varscan2
- KCNQ5 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV59653883; called by muse, mutect2, varscan2
- KCNQ5 | c.2591G>A p.W864* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV59660366; called by muse, varscan2
- KCTD16 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV72578831; called by muse, mutect2, varscan2
- KDM3B | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.282); catalogued as COSV58690803; called by muse, mutect2, varscan2
- KDM5B | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52507805; called by muse, mutect2, varscan2
- KHDC3L | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.104); catalogued as COSV64859234; called by muse, mutect2, varscan2
- KHDRBS3 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV63416075; called by muse, mutect2, varscan2
- KIAA0408 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV64106598; called by muse, mutect2, varscan2
- KIAA1109 | c.4436T>C p.L1479P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs757939105, COSV99166297; called by muse, mutect2, varscan2
- KIAA1109 | c.10585G>A p.G3529R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.08); catalogued as COSV52673454; called by muse, mutect2, varscan2
- KIAA1109 | c.14020C>T p.R4674C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278017597, COSV52663636; called by muse, mutect2, varscan2
- KIAA1841 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54374950, COSV54376935; called by muse, mutect2, varscan2
- KIF21B | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59757890; called by muse, mutect2, varscan2
- KIF26A | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs761864919, COSV59466692; called by muse, mutect2, varscan2
- KIF2B | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52130550; called by muse, mutect2, varscan2
- KIR2DL1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 72/482 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV52409752; called by muse, varscan2
- KIRREL3 | c.79T>A p.C27S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV73106200; called by muse, mutect2, varscan2
- KL | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1271249857, COSV66308812; called by muse, mutect2, varscan2
- KLHL14 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV63832514; called by muse, mutect2, varscan2
- KLK1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV56826929; called by muse, mutect2, varscan2
- KLKB1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146525902; called by muse, mutect2, varscan2
- KMT2A | c.4396C>T p.P1466S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63282023; called by muse, mutect2, varscan2
- KPRP | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1026799830, COSV64221693; called by muse, mutect2, varscan2
- KRT33B | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV52440960; called by muse, mutect2, varscan2
- KRT34 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs529354447, COSV67449832, COSV67450639; called by muse, mutect2, varscan2
- KRT73 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59838000; called by muse, varscan2
- KRTAP10-5 | c.797G>C p.C266S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV59962650, COSV59972538; called by muse, mutect2, varscan2
- KRTAP10-5 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1362677994, COSV59962201; called by muse, mutect2, varscan2
- KRTAP5-6 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.947); catalogued as COSV66289244; called by muse, mutect2, varscan2
- KY | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV71017321; called by muse, mutect2
- L1TD1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as COSV63133502; called by muse, mutect2, varscan2
- LAMA1 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs143022454; called by mutect2, varscan2
- LAMA3 | c.5990G>A p.R1997K (on ENST00000313654 / NM_198129.4; = p.R388K on NM_000227.6) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as COSV52534826; called by muse, mutect2, varscan2
- LAMA3 | c.9642G>T p.K3214N (on ENST00000313654 / NM_198129.4; = p.K1605N on NM_000227.6) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs779131897, CM024110, COSV52534842; called by muse, mutect2, varscan2
- LARGE1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.203); catalogued as COSV61657845; called by muse, mutect2, varscan2
- LCA5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs568193819, COSV63971388; called by muse, mutect2, varscan2
- LDHA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs752156024, COSV57040296; called by muse, mutect2
- LECT2 | c.293T>A p.F98Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV50847126; called by muse, mutect2, varscan2
- LEXM | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV64022702; called by muse, mutect2, varscan2
- LGALS12 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as COSV55369744; called by muse, mutect2, varscan2
- LGI1 | c.13A>T p.R5* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV65058002; called by muse, mutect2, varscan2
- LHCGR | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54294711, COSV54297145; called by muse, mutect2, varscan2
- LHX4 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV55375562; called by muse, mutect2, varscan2
- LIFR | c.3248G>A p.G1083E | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as COSV54690338; called by muse, mutect2, varscan2
- LIFR | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54690362; called by muse, varscan2
- LIFR | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54690385; called by muse, varscan2
- LILRB1 | c.722C>T p.P241L (on ENST00000427581; = p.P205L on NM_006669.6) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs746221743, COSV61118037; called by muse, varscan2
- LILRB4 | c.1030G>A p.E344K (on ENST00000391733 / NM_001278428.3; = p.E343K on NM_001278426.3) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV54404919; called by muse, mutect2, varscan2
- LIMA1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as rs1287510032, COSV57965544, COSV57965796; called by muse, mutect2, varscan2
- LINGO2 | c.630T>A p.H210Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58059804; called by muse, mutect2, varscan2
- LIPE | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV54922956; called by muse, mutect2, varscan2
- LIPK | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs376096296; called by muse, mutect2, varscan2
- LLGL1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as rs780566991, COSV57498057; called by muse, mutect2, varscan2
- LMNA | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs1205208123, COSV61544111; called by mutect2, varscan2
- LMNTD1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV51447110; called by muse, mutect2, varscan2
- LMO7 | c.1942C>T p.P648S (on ENST00000357063; = p.P378S on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV58536698; called by muse, mutect2, varscan2
- LPA | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60295789; called by muse, mutect2, varscan2
- LRBA | c.5002C>T p.P1668S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as rs763711820, COSV63951092; called by muse, mutect2, varscan2
- LRFN2 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs375159497; called by muse, mutect2, varscan2
- LRP1B | c.11009-2A>G p.X3670_splice | Splice Site (SNP) | VAF 37/131 reads (28%) | catalogued as COSV67221320; called by muse, mutect2, varscan2
- LRP4 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV66135889; called by muse, mutect2, varscan2
- LRPPRC | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 162/516 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV53238391; called by muse, mutect2, varscan2
- LRRC37B | c.1911T>A p.N637K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58952558; called by muse, mutect2, varscan2
- LRRC4C | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1172465341, COSV53425970; called by muse, mutect2, varscan2
- LRRC8D | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV61579393; called by muse, mutect2, varscan2
- LRRN2 | c.146A>C p.E49A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65783797; called by muse, mutect2, varscan2
- LRRTM2 | c.1336A>G p.K446E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51220891; called by muse, mutect2, varscan2
- LRTOMT | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99194374; called by muse, mutect2, varscan2
- LSR | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 85/351 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs1194058689, COSV61555109; called by muse, mutect2, varscan2
- LTBP4 | c.3835T>C p.C1279R (on ENST00000308370 / NM_001042544.1; = p.C1242R on NM_003573.2) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52581719; called by muse, mutect2, varscan2
- LTF | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as COSV51607070; called by muse, mutect2, varscan2
- LUZP2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs150458536, COSV61201811; called by muse, varscan2
- LY75 | c.2810C>T p.S937L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs772269318, COSV55102005; called by muse, mutect2, varscan2
- LY75 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55105721; called by muse, mutect2, varscan2
- LY96 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | catalogued as COSV53024777; called by muse, mutect2, varscan2
- MAB21L4 | c.1336G>A p.E446K (on ENST00000388934 / NM_001085437.3; = p.E278K on NM_024861.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs556869324, COSV56743448; called by muse, mutect2, varscan2
- MACC1 | c.2100A>C p.L700F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60543034; called by muse, mutect2, varscan2
- MACF1 | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV58373945; called by muse, mutect2, varscan2
- MACF1 | c.19127A>T p.Y6376F (on ENST00000372915; = p.Y4421F on NM_012090.5) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs570868296, COSV57121470; called by muse, mutect2, varscan2
- MADD | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs757300995, COSV60624292; called by muse, mutect2, varscan2
- MAGEA12 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs1556833443, COSV63294831; called by muse, mutect2, varscan2
- MAGEB18 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); catalogued as COSV100305620, COSV57464032; called by muse, varscan2
- MAGI1 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs766879624, COSV58323562; called by muse, mutect2, varscan2
- MAN2C1 | c.1671C>A p.F557L | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV51228883; called by muse, mutect2, varscan2
- MAP10 | c.2774C>T p.T925I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV69363626; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV61010051; called by muse, mutect2
- MAP2 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52291314; called by muse, mutect2, varscan2
- MAP3K21 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64044668; called by muse, mutect2, varscan2
- MAP3K5 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 70/222 reads (32%) | catalogued as COSV62889215; called by muse, mutect2, varscan2
- MAP3K9 | c.1341G>A p.W447* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV67121363; called by muse, mutect2, varscan2
- MAP6 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV59075811; called by muse, mutect2, varscan2
- MAP7 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.787); catalogued as rs891685890, COSV63419769; called by muse, mutect2, varscan2
- MAST4 | c.928C>T p.Q310* (on ENST00000403625 / NM_001164664.2; = p.Q121* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99844617; called by muse, mutect2, varscan2
- MCHR2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs767801578, COSV56003223; called by muse, mutect2, varscan2
- MCM10 | c.2190A>T p.E730D (on ENST00000484800 / NM_182751.3; = p.E729D on NM_018518.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101098196; called by mutect2, varscan2
- MCM4 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208999169, COSV50623515; called by muse, mutect2, varscan2
- MCTP1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs749205654, COSV56513928, COSV56516227; called by muse, mutect2, varscan2
- MDC1 | c.5107C>T p.P1703S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV64524634; called by muse, mutect2, varscan2
- MDM1 | c.1949G>C p.R650T | Missense Mutation (SNP) | VAF 19/684 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57446036; called by muse, mutect2
- MECOM | c.253C>T p.P85S (on ENST00000468789 / NM_001105078.4; = p.P273S on NM_004991.4) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV52963255; called by muse, mutect2, varscan2
- MED25 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57204466; called by muse, mutect2, varscan2
1,554 further variants in this file (796 protein-altering or splice-affecting, 711 silent, 47 other) are not listed here.
